Somatic mutation profile of tumor specimen TCGA-19-1790-01B (aliquot TCGA-19-1790-01B-01D-1353-08) from TCGA case TCGA-19-1790, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.5 years (20,626 days).
Specimen TCGA-19-1790-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2e278bd-56fd-449b-aef8-bf4ec7dac685.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-1790-10B (Blood Derived Normal), aliquot TCGA-19-1790-10B-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/321d0b53-2d86-489f-b3c5-445850aa12f8

The open-access MAF lists 87 somatic variants for this specimen: 67 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 17, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, 3'Flank 1, 3'UTR 1, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PAH | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs62508698, CM890094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs369079165, COSV52030947; called by muse, mutect2, varscan2
- ADCY7 | c.3189G>T p.R1063S | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV54266724; called by muse, mutect2, varscan2
- AHNAK | c.2377A>T p.S793C | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV57213055; called by muse, mutect2, varscan2
- AL645922.1 | c.2110C>T p.R704W | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs537478097, COSV54960553; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- AMPH | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375161752; called by muse, mutect2, varscan2
- CALD1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs142583902; called by mutect2, varscan2
- CD7 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs781698663, COSV53939448; called by muse, mutect2, varscan2
- CDA | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV66751697; called by muse, mutect2, varscan2
- CDH18 | c.1623C>G p.D541E | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV56921055; called by muse, mutect2, varscan2
- CFAP47 | c.2765G>A p.G922D | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.099); catalogued as COSV52884468; called by muse, mutect2, varscan2
- CHSY1 | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV54253242; called by muse, mutect2, varscan2
- CIB4 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs370969445, COSV56600636; called by muse, mutect2, varscan2
- DMBT1 | c.6289C>T p.R2097* (on ENST00000338354 / NM_001377530.1; = p.R1340* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as rs1265509713, COSV57543681; called by muse, mutect2, varscan2
- EPHA5 | c.976A>T p.S326C | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56629190, COSV56644684; called by muse, mutect2, varscan2
- ESR1 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV52790518; called by muse, mutect2, varscan2
- FGB | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV57418291; called by muse, varscan2
- FOXA1 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV51645765; called by muse, mutect2, varscan2
- HBE1 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV53079990, COSV53080012; called by muse, mutect2, varscan2
- HRG | c.781C>A p.H261N | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.147); catalogued as COSV51645559; called by muse, mutect2, varscan2
- IKZF3 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV53102162; called by muse, mutect2, varscan2
- KRT74 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59771389, COSV59773434; called by muse, mutect2, varscan2
- MECOM | c.928G>A p.G310S (on ENST00000468789 / NM_001105078.4; = p.G498S on NM_004991.4) | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.158); catalogued as rs774213367, COSV52963731; called by muse, mutect2, varscan2
- MUC3A | c.7618C>A p.L2540I | Missense Mutation (SNP) | VAF 60/408 reads (15%) | SIFT deleterious, low confidence (0.01); catalogued as COSV100114354; called by mutect2, varscan2
- MYO5B | c.3207C>A p.N1069K | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs768343996, COSV53218341; called by muse, mutect2, varscan2
- NAGS | c.1548C>A p.N516K | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); catalogued as COSV52813250; called by muse, mutect2, varscan2
- OOSP2 | c.305A>T p.D102V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV53928792; called by muse, mutect2, varscan2
- OR2K2 | c.791A>G p.K264R (on ENST00000374428; = p.K235R on NM_205859.2) | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57016957; called by muse, mutect2, varscan2
- OR4K14 | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758762057, COSV59293047; called by muse, mutect2, varscan2
- OR52L1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV59987023; called by muse, varscan2
- OR5D14 | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV59456275; called by muse, mutect2, varscan2
- OR5K2 | c.227C>G p.A76G | Missense Mutation (SNP) | VAF 73/381 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV71143178; called by muse, mutect2, varscan2
- OR6Q1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 95/329 reads (29%) | catalogued as rs369989982; called by muse, mutect2, varscan2
- PAX3 | c.735C>G p.D245E | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV60588346; called by muse, mutect2, varscan2
- PAX8 | c.656C>A p.P219H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as COSV54508493; called by muse, mutect2, varscan2
- PGK2 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1413479688, COSV59163824; called by muse, mutect2, varscan2
- PLCH1 | c.4929A>T p.K1643N (on ENST00000340059 / NM_001130960.2; = p.K1635N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.009); catalogued as COSV58196919; called by muse, mutect2, varscan2
- POM121L12 | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.664); catalogued as COSV68692936; called by muse, mutect2, varscan2
- PPP1R12B | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as COSV61116910; called by muse, mutect2, varscan2
- PPP2R3A | c.1267G>T p.G423* | Nonsense Mutation (SNP) | VAF 33/106 reads (31%) | catalogued as COSV53863695; called by muse, mutect2, varscan2
- PRAMEF12 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63215265; called by muse, mutect2
- PXYLP1 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 84/258 reads (33%) | catalogued as COSV53890399; called by muse, varscan2
- RMC1 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV52571877; called by muse, mutect2, varscan2
- RNF17 | c.900C>A p.N300K | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55040312; called by muse, mutect2, varscan2
- RPP30 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs185152546; called by muse, mutect2
- SETD9 | c.385A>G p.S129G | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53650339; called by muse, mutect2, varscan2
- SLFN13 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.285); catalogued as rs148604980; called by muse, varscan2
- SLIT2 | c.3561+2T>A p.X1187_splice | Splice Site (SNP) | VAF 5/87 reads (6%) | catalogued as COSV56571991; called by muse, mutect2
- SULT2B1 | c.553C>A p.Q185K (on ENST00000201586 / NM_177973.2; = p.Q170K on NM_004605.2) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.214); catalogued as COSV99572155; called by muse, mutect2
- SYDE2 | c.3294C>G p.N1098K | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV100415722, COSV58322937; called by muse, mutect2, varscan2
- TCF12 | c.1182C>G p.H394Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV51006089; called by muse, mutect2, varscan2
- TCF3 | c.1172G>C p.S391T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV53648397; called by muse, mutect2, varscan2
- TCHH | c.5233C>T p.R1745C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs760326208, COSV64274740; called by muse, mutect2, varscan2
- TNS3 | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 151/664 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.054); catalogued as rs1309090682, COSV60790855; called by muse, mutect2, varscan2
- TRPS1 | c.2152del p.E718Nfs*33 (on ENST00000220888 / NM_001330599.2; = p.E731Nfs*33 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 61/288 reads (21%) | catalogued as COSV55228905; called by mutect2, pindel, varscan2
- TRPS1 | c.106G>A p.E36K (on ENST00000220888 / NM_001330599.2; = p.E49K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV55227703, COSV55239728; called by muse, mutect2
- TUBGCP3 | c.1517T>A p.M506K | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56186764; called by muse, mutect2, varscan2
- VCX3B | c.25G>T p.G9* | Nonsense Mutation (SNP) | VAF 41/135 reads (30%) | catalogued as COSV66842686; called by muse, mutect2, varscan2
- ZNF347 | c.928A>T p.I310F | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.331); catalogued as COSV61968706; called by muse, mutect2, varscan2
- AKAP9 | c.4683_4684insGA p.R1562Efs*20 | Frame Shift Ins (INS) | VAF 20/108 reads (19%) | called by pindel, varscan2
- FAM217A | c.1519_1521del p.Q507del | In Frame Del (DEL) | VAF 42/139 reads (30%) | called by mutect2, pindel, varscan2
- PIK3CA | c.1387_1404+2del p.X463_splice | Splice Site (DEL) | VAF 26/182 reads (14%) | called by mutect2, pindel
- SALL3 | c.3589del p.Q1197Rfs*9 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- STARD3NL | c.303+4_303+7del p.X101_splice | Splice Site (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel
- TRAV27 | c.104A>T p.E35V | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZAN | c.2295del p.K765Nfs*236 | Frame Shift Del (DEL) | VAF 21/91 reads (23%) | called by mutect2, varscan2
- ANK1 | c.4869C>T p.D1623= | Silent (SNP) | VAF 39/324 reads (12%) | catalogued as rs776829174, COSV55881341; called by muse, mutect2, varscan2
- ARID1A | c.3795C>T p.G1265= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV61377454; called by muse, mutect2, varscan2
- CDX4 | c.735G>A p.S245= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1315965332, COSV65171658, COSV65171907; called by muse, mutect2, varscan2
- CREB3L1 | c.273C>T p.S91= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs755740355, COSV55831203; called by muse, mutect2, varscan2
- DHX34 | c.2535C>T p.F845= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs571902778, COSV60895378; called by muse, mutect2, varscan2
- DSG4 | c.474G>A p.S158= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs201177179, COSV57391573; called by muse, mutect2, varscan2
- KCNA1 | c.495C>T p.P165= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV101230181; called by muse, mutect2, varscan2
- MUC17 | c.228C>T p.V76= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs755764209, COSV60282555; called by muse, mutect2, varscan2
- NIPBL | c.8067A>G p.K2689= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV56950958; called by muse, mutect2, varscan2
- PPP1R3A | c.642T>G p.S214= | Silent (SNP) | VAF 38/202 reads (19%) | catalogued as COSV52882391; called by muse, mutect2, varscan2
- PSG5 | c.348C>T p.D116= | Silent (SNP) | VAF 138/720 reads (19%) | catalogued as rs143404539; called by muse, mutect2, varscan2
- RAB11FIP5 | c.696A>G p.K232= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as COSV50249374; called by muse, mutect2, varscan2
- RTTN | c.5250C>A p.L1750= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as COSV55344710; called by muse, mutect2, varscan2
- SHCBP1L | c.30C>T p.P10= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1376020945, COSV62354950; called by muse, mutect2
- SLC1A2 | c.1017G>A p.V339= | Silent (SNP) | VAF 60/263 reads (23%) | catalogued as COSV53521341, COSV99554172; called by muse, mutect2, varscan2
- TMEFF2 | c.366A>G p.K122= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV55832525; called by muse, mutect2, varscan2
- ZNF565 | c.1377C>T p.Y459= (on ENST00000355114; = p.Y419= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as rs774051105, COSV58410884; called by muse, mutect2, varscan2
- COPS9 | chr2:240129917 C>T | 3'Flank (SNP) | VAF 8/76 reads (11%) | catalogued as rs551865042, COSV56228042; called by mutect2, varscan2
- FGFR3 | c.*864G>A | 3'UTR (SNP) | VAF 29/142 reads (20%) | catalogued as rs1462697338, COSV53401260; ClinVar: uncertain significance; called by muse, varscan2
- ZNF33A | chr10:38010661 C>G | 5'Flank (SNP) | VAF 12/61 reads (20%) | catalogued as rs1187035581, COSV100275655; called by muse, mutect2, varscan2
